Somatic mutation profile of tumor specimen TARGET-10-PARUBX-09A (aliquot TARGET-10-PARUBX-09A-01D) from TARGET case TARGET-10-PARUBX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,771 days).
Specimen TARGET-10-PARUBX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 956f3fad-eef5-48eb-8a7d-a4d407be0ef4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUBX-10A (Blood Derived Normal), aliquot TARGET-10-PARUBX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fde5991-6bfc-43c4-8869-abde1d57e9b6

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD163 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs750296031, COSV63131574; called by muse, mutect2, varscan2
- EPB41L4B | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751107003, COSV65796997; called by muse, mutect2, varscan2
- TAFA1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765684057, COSV72037005; called by muse, mutect2, varscan2
- VRTN | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1350307582, COSV56443412; called by muse, mutect2, varscan2
- ZNF716 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs781956725; called by muse, mutect2, varscan2
- MTMR11 | c.68del p.S23Lfs*30 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- ZNF710 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKD1 | c.1672+72C>T | Intron (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
